Somatic mutation profile of cancer-model specimen HCM-CSHL-0081-C25-85B (3D Organoid; aliquot HCM-CSHL-0081-C25-85B-01D-A78M-36), derived from the primary tumor of HCMI case HCM-CSHL-0081-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 57.9 years (21,139 days).
Specimen HCM-CSHL-0081-C25-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65851c7d-fd6a-4e52-90f5-082de2d01363.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0081-C25-11A (Solid Tissue Normal), aliquot HCM-CSHL-0081-C25-11A-11D-A78M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55599c85-b69a-484b-bf70-206374deada9

The open-access MAF lists 61 somatic variants for this specimen: 39 protein-altering or splice-affecting, 14 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 14, Intron 4, Splice Site 3, Translation Start Site 1, 3'UTR 1, Splice Region 1, RNA 1, Nonsense Mutation 1, In Frame Del 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 115/253 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 168/175 reads (96%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANKFN1 | c.3799C>T p.R1267C (on ENST00000653862; = p.R1120C on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs764552239, COSV73720123; called by muse, mutect2, varscan2
- ANKRD44 | c.1650+8G>T | Splice Region (SNP) | VAF 113/272 reads (42%) | catalogued as rs1559044801; called by muse, varscan2
- CPXM2 | c.2242C>T p.R748W | Missense Mutation (SNP) | VAF 90/174 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs1455207884, COSV53867011, COSV53869728; called by muse, mutect2, varscan2
- CT47B1 | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 116/116 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs1000436269; called by mutect2, varscan2
- FKBP9 | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.381); catalogued as rs375139220; called by muse, varscan2
- GLT6D1 | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 106/140 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs183429273; called by muse, mutect2, varscan2
- IKBKB | c.2112G>C p.K704N | Missense Mutation (SNP) | VAF 96/259 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100645818; called by muse, mutect2, varscan2
- KCNA3 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63902574; called by muse, mutect2, varscan2
- KIF1B | c.5180G>A p.R1727Q (on ENST00000377086 / NM_001365952.1; = p.R1681Q on NM_015074.3) | Missense Mutation (SNP) | VAF 73/400 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs969290629, COSV55803801; called by muse, mutect2, varscan2
- MCM4 | c.1834T>A p.S612T | Missense Mutation (SNP) | VAF 52/437 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs564114660; called by muse, mutect2, varscan2
- NFASC | c.1076G>A p.R359Q (on ENST00000339876 / NM_001378329.1; = p.R370Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/311 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs767453033, COSV58366173; called by muse, mutect2, varscan2
- OR8J3 | c.515A>C p.N172T | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs1386891929; called by muse, mutect2, varscan2
- OR9I1 | c.364C>G p.R122G | Missense Mutation (SNP) | VAF 80/193 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100110371; called by muse, mutect2, varscan2
- TECTA | c.1190A>G p.Y397C | Missense Mutation (SNP) | VAF 103/217 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.75); catalogued as rs918069755; called by muse, mutect2, varscan2
- TEX13A | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 201/209 reads (96%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs1412367990, COSV100782132, COSV61161595; called by muse, mutect2, varscan2
- AC093155.3 | c.-4_8del | Translation Start Site (DEL) | VAF 43/130 reads (33%) | called by mutect2, pindel, varscan2
- CCDC18 | c.2200A>T p.I734F (on ENST00000343253 / NM_001306076.1; = p.I735F on NM_206886.4) | Missense Mutation (SNP) | VAF 60/117 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- CFAP65 | c.4157T>G p.V1386G | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CR1 | c.274T>A p.W92R | Missense Mutation (SNP) | VAF 89/154 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DPYS | c.456T>A p.D152E | Missense Mutation (SNP) | VAF 136/502 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF2D | c.1052+2T>C p.X351_splice | Splice Site (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- KCNJ1 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LPIN1 | c.2314C>G p.P772A | Missense Mutation (SNP) | VAF 69/169 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- MYH11 | c.4366T>G p.L1456V | Missense Mutation (SNP) | VAF 165/373 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- MYH9 | c.4156G>A p.V1386M | Missense Mutation (SNP) | VAF 174/304 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PANK4 | c.2227C>A p.L743I | Missense Mutation (SNP) | VAF 151/366 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- PITRM1 | c.1251G>T p.E417D | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POLE | c.670T>G p.Y224D | Missense Mutation (SNP) | VAF 107/110 reads (97%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PRKD1 | c.1393-1G>C p.X465_splice | Splice Site (SNP) | VAF 12/71 reads (17%) | called by muse, varscan2
- RABGEF1 | c.122A>G p.N41S (on ENST00000439720 / NM_001287061.2; = p.N28S on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/34 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF150 | c.960G>A p.M320I | Missense Mutation (SNP) | VAF 103/226 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- ROS1 | c.6088G>T p.E2030* | Nonsense Mutation (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- SETX | c.1177C>G p.L393V | Missense Mutation (SNP) | VAF 43/256 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SIPA1L3 | c.3662-1G>T p.X1221_splice | Splice Site (SNP) | VAF 72/149 reads (48%) | called by muse, mutect2, varscan2
- STK11 | c.433del p.E145Rfs*16 | Frame Shift Del (DEL) | VAF 107/153 reads (70%) | called by mutect2, pindel, varscan2
- UBASH3B | c.755_757del p.R252_F253delinsL | In Frame Del (DEL) | VAF 34/141 reads (24%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.9634C>A p.P3212T | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHTF18 | c.99G>A p.S33= | Silent (SNP) | VAF 63/115 reads (55%) | catalogued as rs1043211685; called by muse, mutect2, varscan2
- DDX27 | c.102G>A p.A34= | Silent (SNP) | VAF 148/309 reads (48%) | catalogued as rs112518064, COSV65629814; called by muse, mutect2, varscan2
- DNAH3 | c.3450C>T p.N1150= | Silent (SNP) | VAF 126/320 reads (39%) | catalogued as rs1251598012; called by muse, mutect2
- FBXW5 | c.54C>T p.F18= | Silent (SNP) | VAF 235/316 reads (74%) | catalogued as rs775259992; called by muse, mutect2, varscan2
- GDF6 | c.534G>C p.G178= | Silent (SNP) | VAF 24/272 reads (9%) | called by muse, mutect2
- GRK7 | c.33C>T p.I11= | Silent (SNP) | VAF 39/70 reads (56%) | catalogued as rs868864461; called by muse, mutect2, varscan2
- IGHG2 | c.471C>T p.Y157= | Silent (SNP) | VAF 235/471 reads (50%) | catalogued as rs374420820; called by muse, mutect2, varscan2
- MYPN | c.2691A>G p.R897= | Silent (SNP) | VAF 131/288 reads (45%) | called by muse, mutect2, varscan2
- OR1J1 | c.762A>T p.T254= | Silent (SNP) | VAF 46/235 reads (20%) | called by muse, mutect2, varscan2
- PTX4 | c.1149G>A p.V383= (on ENST00000447419 / NM_001328608.2; = p.V378= on NM_001013658.1) | Silent (SNP) | VAF 74/146 reads (51%) | catalogued as rs1379329224; called by muse, mutect2, varscan2
- RP1 | c.868T>C p.L290= | Silent (SNP) | VAF 48/158 reads (30%) | catalogued as COSV55115442; called by muse, mutect2, varscan2
- SALL3 | c.1887G>A p.T629= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs991618333, COSV101609956; called by muse, mutect2, varscan2
- TLR6 | c.1674T>A p.S558= | Silent (SNP) | VAF 117/218 reads (54%) | called by muse, mutect2, varscan2
- TMEM132B | c.2674A>C p.R892= | Silent (SNP) | VAF 59/117 reads (50%) | called by muse, mutect2, varscan2
- AC012464.1 | chr12:93894072 del G | 3'Flank (DEL) | VAF 102/145 reads (70%) | called by mutect2, pindel, varscan2
- AMACR | c.739+1138_739+1139insA | Intron (INS) | VAF 53/104 reads (51%) | called by mutect2, pindel, varscan2
- CCDC162P | n.5826G>A | RNA (SNP) | VAF 45/102 reads (44%) | catalogued as rs1007371686; called by muse, mutect2, varscan2
- DCDC1 | c.2715+8769A>C | Intron (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2, varscan2
- KCNJ10 | c.*32C>T | 3'UTR (SNP) | VAF 77/169 reads (46%) | called by muse, mutect2, varscan2
- MDM2 | c.175-1135_175-1128del | Intron (DEL) | VAF 82/130 reads (63%) | called by mutect2, pindel, varscan2
- TANGO2 | c.380+161G>T | Intron (SNP) | VAF 78/154 reads (51%) | catalogued as rs781272776; called by muse, mutect2, varscan2
- USP27X | chrX:49878441 G>C | 5'Flank (SNP) | VAF 301/304 reads (99%) | called by muse, mutect2, varscan2
